CPTAC case C3N-00179 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f95bc5d4-302b-46f8-87ec-c8cee519e54c

Demographics
Sex at birth: male; Race: asian; Year of birth: 1947; Vital status: Dead; Days to death: 85 days; Year of death: 2016; Country of birth: Vietnam.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 69.5 years (25,370 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T4b; AJCC pathologic N: N3; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Residual disease: R0; Days to last known disease status: 85 days; Days to last follow up: 85 days; Clark level: V; Tumor focality: Unifocal; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 2 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 13; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 85.

Other clinical attributes
- Weight: 67 kg; Height: 166 cm; BMI: 24.31.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 15; Cigarettes per day: 10; Tobacco smoking onset year: 1986; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 36.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-00179-01, C3N-00179-02 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-00179-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 300 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00179-23: Section location: foot and lymph node; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-00179-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 300 mg.
- Sample C3N-00179-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -2 days; Initial weight: 200 mg; Time between clamping and freezing: 29 minutes; Time between excision and freezing: 9 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00179-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Sample C3N-00179-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
